Somatic mutation profile of tumor specimen TARGET-20-PARDRM-03A (aliquot TARGET-20-PARDRM-03A-01D) from TARGET case TARGET-20-PARDRM, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.5 years (4,567 days).
Specimen TARGET-20-PARDRM-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fea4bf53-9ebd-4881-95f3-e323277e6b48.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARDRM-14A (Bone Marrow Normal), aliquot TARGET-20-PARDRM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2fddcc4-66b9-42ce-a67d-448b77afd560

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Frame Shift Ins 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 65/204 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 22/280 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- WT1 | c.1101dup p.R368Tfs*5 | Frame Shift Ins (INS) | VAF 22/228 reads (10%) | catalogued as COSV100189346, COSV60065589, COSV60066153, COSV60066283, COSV60067539, COSV60069909, COSV60077657, COSV60077667, COSV60077683, COSV60078403, COSV60079676, COSV60084998, COSV60085351; called by mutect2, pindel
- CREBBP | c.1455_1456insAGGCCCAT p.A486Rfs*11 | Frame Shift Ins (INS) | VAF 34/124 reads (27%) | called by mutect2, pindel, varscan2
- GATA2 | c.1153_1164del p.P385_M388del | In Frame Del (DEL) | VAF 46/171 reads (27%) | called by mutect2, pindel, varscan2
- DACH1 | c.*362T>G | 3'UTR (SNP) | VAF 114/236 reads (48%) | called by muse, mutect2, varscan2
